CCDI case PBBUNX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/806618ca-84d8-454d-85af-e6a3c815bb72

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pinealoma: ICD-O-3 morphology code: 9360/1; Tissue or organ of origin: Pineal gland; Age at diagnosis: 17.3 years (6,307 days).

Biospecimens (3 samples)
- Sample 0DHMLV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHMNQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHMSC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
